Gene-level copy-number profile of tumor specimen C3N-03057-02 from CPTAC case C3N-03057, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 61.4 years (22,417 days).
Specimen C3N-03057-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 529ff6d3-51bb-4e3a-a5ab-0a0fdab8dd3c.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-03057-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,744 have no estimate.
https://portal.gdc.cancer.gov/files/47e8f7c9-d001-4f0c-be8b-fffe6643041a

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 1,620; copy number 1: 18,883; copy number 2: 34,395; copy number 3: 3,542; copy number 4: 374; copy number 5: 2; copy number 6: 19; copy number 7: 44.

Homozygous deletions (total copy number 0; autosomes only): 1,147 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:64,091–12,177,550, 298 genes (broad region; genes not listed).
- chr8:12,570,350–43,674,591, 592 genes (broad region; genes not listed).
- chr9:12,134–14,594,200, 186 genes (broad region; genes not listed).
- chr9:78,150,532–83,713,378, 61 genes (broad region; genes not listed).
- chr15:28,545,912–28,685,264, 6 genes: AC138749.3, AC138749.1, AC138749.2, HERC2P11, HERC2P9, AC055876.2.
- chr15:32,583,612–32,615,111, 2 genes (within-gene range 0–5): AC123768.3, AC123768.1.
- chr19:43,211,791–43,269,530, 2 genes: CEACAMP10, PSG9.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 2 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr15:32,461,666–32,461,809, 1 gene, copy number 5: AC135983.5.
- chr15:32,536,047–32,587,613, 1 gene, copy number 5 (within-gene range 0–5): LINC02256.

Autosomal genes at a single copy (total copy number 1): 18,149. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
